Somatic mutation profile of tumor specimen TCGA-DD-AACQ-01A (aliquot TCGA-DD-AACQ-01A-11D-A40R-10) from TCGA case TCGA-DD-AACQ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 50.5 years (18,429 days).
Specimen TCGA-DD-AACQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2681fdde-4489-4a0f-9b73-db0b7439ae85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACQ-10A (Blood Derived Normal), aliquot TCGA-DD-AACQ-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9700429-f048-4080-8edc-2041df30f78d

The open-access MAF lists 233 somatic variants for this specimen: 182 protein-altering or splice-affecting, 47 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 147, Silent 47, Nonsense Mutation 13, Frame Shift Del 8, Splice Site 6, Splice Region 5, RNA 4, In Frame Del 1, Nonstop Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS2 | c.2695T>A p.S899T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99283767; called by muse, mutect2, varscan2
- ADCY9 | c.1817A>T p.Q606L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV99570840; called by muse, mutect2, varscan2
- ADHFE1 | c.185A>T p.K62M | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV99398161; called by muse, mutect2, varscan2
- ADRB3 | c.1226A>T p.*409Lext*2 | Nonstop Mutation (SNP) | VAF 43/55 reads (78%) | catalogued as COSV100799990; called by muse, mutect2, varscan2
- AGRP | c.83T>A p.M28K | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99341336; called by muse, mutect2, varscan2
- AKR1C1 | c.10A>G p.K4E | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV101080567; called by muse, mutect2, varscan2
- ANXA2 | c.29A>T p.K10M | Missense Mutation (SNP) | VAF 177/381 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100222136; called by muse, mutect2, varscan2
- AQP1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.636); catalogued as rs546847577, COSV61266989; called by muse, mutect2, varscan2
- ARAP3 | c.3445A>T p.N1149Y | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99500249; called by muse, mutect2, varscan2
- ARFGAP1 | c.718-2A>T p.X240_splice | Splice Site (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100796726; called by muse, mutect2, varscan2
- ARHGAP24 | c.97G>T p.V33F | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs1162456065, COSV101233326; called by muse, mutect2, varscan2
- ARHGEF10L | c.2330C>G p.P777R | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); catalogued as COSV99393786; called by muse, mutect2
- ASAP2 | c.1978A>T p.I660F | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99856758; called by muse, mutect2, varscan2
- ASXL3 | c.2572A>G p.T858A | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV99326471; called by muse, mutect2, varscan2
- ATP1A4 | c.1206T>A p.D402E | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100927641; called by muse, mutect2, varscan2
- ATR | c.3059A>T p.Q1020L | Missense Mutation (SNP) | VAF 167/371 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV100638571; called by muse, mutect2, varscan2
- ATXN7L3 | c.793A>T p.S265C (on ENST00000389384 / NM_001382309.1; = p.S272C on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV100116322; called by muse, mutect2, varscan2
- AVPR1B | c.902A>T p.Q301L | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100899455; called by muse, mutect2, varscan2
- BEND3 | c.2282A>T p.Y761F | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); catalogued as COSV100944634; called by muse, mutect2, varscan2
- C1QTNF9B | c.424A>G p.I142V | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs750166217, COSV101158633; called by muse, mutect2, varscan2
- CACNA2D1 | c.3026T>A p.M1009K (on ENST00000356253 / NM_001366867.1; = p.M997K on NM_000722.4) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV100667247; called by muse, mutect2, varscan2
- CADM3 | c.787del p.Q263Sfs*14 (on ENST00000368125 / NM_001127173.3; = p.Q297Sfs*14 on NM_021189.5) | Frame Shift Del (DEL) | VAF 51/180 reads (28%) | catalogued as COSV63686500; called by mutect2, pindel, varscan2
- CAMKK2 | c.1028T>A p.L343H | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV100243187; called by muse, mutect2, varscan2
- CD207 | c.854A>T p.E285V | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101338592; called by muse, mutect2, varscan2
- CEP250 | c.5159A>T p.Q1720L | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV100699176; called by muse, mutect2, varscan2
- CEP78 | c.16A>T p.K6* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as COSV99450889; called by muse, mutect2, varscan2
- CFAP61 | c.699+2T>A p.X233_splice | Splice Site (SNP) | VAF 38/91 reads (42%) | catalogued as COSV99846592; called by muse, mutect2, varscan2
- CFHR5 | c.961A>T p.M321L | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99889696; called by muse, mutect2, varscan2
- CHAMP1 | c.1294A>T p.S432C | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV100778870; called by muse, mutect2, varscan2
- CHD5 | c.907A>T p.S303C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV52413114, COSV99314945; called by muse, mutect2, varscan2
- CHRNA9 | c.854T>C p.M285T | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100039109; called by muse, mutect2, varscan2
- CLEC12B | c.544A>G p.I182V | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100139094; called by muse, mutect2, varscan2
- COL16A1 | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 100/267 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as COSV99595392; called by muse, mutect2, varscan2
- COL1A1 | c.4252C>G p.H1418D | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56803792, COSV99867452, COSV99868099; called by muse, mutect2, varscan2
- COPRS | c.511A>T p.K171* | Nonsense Mutation (SNP) | VAF 51/134 reads (38%) | catalogued as COSV100188413; called by muse, mutect2, varscan2
- CPB1 | c.290T>A p.L97Q | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99294512; called by muse, mutect2
- CREBBP | c.3607A>T p.K1203* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as COSV99271879; called by muse, mutect2, varscan2
- CRMP1 | c.95A>T p.Y32F | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.057); catalogued as COSV100272333; called by muse, mutect2, varscan2
- CROCC | c.3321G>T p.R1107= | Splice Region (SNP) | VAF 43/97 reads (44%) | catalogued as rs1387308936, COSV100978398; called by muse, mutect2, varscan2
- CSF2RB | c.2017G>T p.G673C | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.594); catalogued as COSV99454423; called by muse, mutect2, varscan2
- CSPG5 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs371926119; called by muse, mutect2, varscan2
- CTSS | c.787A>T p.R263* | Nonsense Mutation (SNP) | VAF 33/82 reads (40%) | catalogued as COSV100935032; called by muse, mutect2, varscan2
- CYLC1 | c.343T>C p.Y115H | Missense Mutation (SNP) | VAF 219/253 reads (87%) | SIFT tolerated (0.12); PolyPhen benign (0.385); catalogued as COSV100255461; called by muse, mutect2, varscan2
- DAB2IP | c.1745A>T p.E582V (on ENST00000408936; = p.E554V on NM_032552.3) | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99406299; called by muse, mutect2, varscan2
- DEDD2 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.339); catalogued as rs1568447720, COSV100260363; called by muse, mutect2, varscan2
- DEFB129 | c.524T>A p.L175Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.421); catalogued as COSV99857538; called by muse, mutect2, varscan2
- DGKD | c.227A>T p.K76M (on ENST00000264057 / NM_152879.3; = p.K32M on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99897542; called by muse, mutect2, varscan2
- DKKL1 | c.272A>T p.Q91L | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.219); catalogued as COSV99678795; called by muse, mutect2, varscan2
- DNAH11 | c.10639A>T p.I3547L | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV100180731; called by muse, mutect2, varscan2
- DNAH3 | c.3084T>A p.T1028= | Splice Region (SNP) | VAF 98/208 reads (47%) | catalogued as COSV99770471; called by muse, mutect2, varscan2
- DNAH5 | c.11279T>A p.L3760Q | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99453966; called by muse, mutect2, varscan2
- DOCK8 | c.5147G>T p.G1716V | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101210070; called by muse, mutect2, varscan2
- DZIP3 | c.3460A>T p.N1154Y | Missense Mutation (SNP) | VAF 122/264 reads (46%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as COSV100848073; called by muse, mutect2, varscan2
- EEA1 | c.4039A>T p.R1347* | Nonsense Mutation (SNP) | VAF 39/80 reads (49%) | catalogued as COSV100468474; called by muse, mutect2, varscan2
- EGFL7 | c.709G>C p.G237R | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.131); catalogued as COSV100452053; called by muse, mutect2, varscan2
- EPG5 | c.3215A>T p.Q1072L | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as COSV56346933, COSV56352658; called by muse, mutect2
- EPS8L3 | c.1478C>A p.A493E (on ENST00000361965 / NM_133181.4; = p.A463E on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs549152937, COSV100719753, COSV62609407; called by muse, mutect2, varscan2
- EVC2 | c.3497A>T p.H1166L | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV100186846; called by muse, mutect2, varscan2
- EXOC3L2 | c.1352T>A p.L451Q | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99374638; called by muse, mutect2, varscan2
- FAM135B | c.87G>C p.Q29H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV99356590, COSV99358110; called by muse, mutect2, varscan2
- FER1L6 | c.4570T>C p.Y1524H | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as COSV101206175; called by muse, mutect2, varscan2
- FLYWCH1 | c.871A>C p.K291Q (on ENST00000253928 / NM_001308068.2; = p.K290Q on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1163174785, COSV99559229; called by muse, mutect2, varscan2
- GAST | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); catalogued as rs1362342224, COSV61475432; called by muse, mutect2, varscan2
- GFUS | c.541A>T p.N181Y | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV99643659; called by muse, mutect2, varscan2
- GGCX | c.952A>T p.K318* | Nonsense Mutation (SNP) | VAF 84/209 reads (40%) | catalogued as COSV99290176; called by muse, mutect2, varscan2
- GLB1L | c.762T>A p.Y254* | Nonsense Mutation (SNP) | VAF 84/178 reads (47%) | catalogued as COSV99850881; called by muse, mutect2, varscan2
- GPM6B | c.230A>T p.H77L | Missense Mutation (SNP) | VAF 186/210 reads (89%) | SIFT tolerated (0.18); PolyPhen benign (0.345); catalogued as COSV100366518; called by muse, mutect2, varscan2
- GREM1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.074); catalogued as rs868208266, COSV55714585; called by muse, mutect2, varscan2
- GRPR | c.1114A>T p.S372C | Missense Mutation (SNP) | VAF 51/65 reads (78%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV100977700; called by muse, mutect2, varscan2
- GUCY1A1 | c.1100A>T p.K367I | Missense Mutation (SNP) | VAF 45/54 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99638638; called by muse, mutect2, varscan2
- HEATR5B | c.3658G>C p.D1220H | Missense Mutation (SNP) | VAF 89/235 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV99250199; called by muse, mutect2, varscan2
- HERC2 | c.5258A>G p.K1753R | Missense Mutation (SNP) | VAF 97/231 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99876616; called by muse, mutect2, varscan2
- HMMR | c.2029A>T p.N677Y | Missense Mutation (SNP) | VAF 149/357 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.055); catalogued as COSV100701049; called by muse, mutect2, varscan2
- IFNLR1 | c.595A>T p.R199* | Nonsense Mutation (SNP) | VAF 46/126 reads (37%) | catalogued as COSV100552303; called by muse, mutect2, varscan2
- IGFL1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV101473074; called by muse, mutect2, varscan2
- IL34 | c.374T>A p.L125Q | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV99852002; called by muse, mutect2, varscan2
- IL6R | c.650A>T p.D217V | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100691107; called by muse, mutect2, varscan2
- IRF9 | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.92); PolyPhen benign (0.021); catalogued as COSV100138275; called by muse, mutect2, varscan2
- IRF9 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as COSV100138276; called by muse, mutect2, varscan2
- ITPK1 | c.628G>T p.V210F | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV99968945; called by muse, mutect2, varscan2
- KANK4 | c.686A>T p.Q229L | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100587694; called by muse, mutect2, varscan2
- KEAP1 | c.289A>T p.K97* | Nonsense Mutation (SNP) | VAF 33/45 reads (73%) | catalogued as rs1425671494, COSV50292215; called by muse, mutect2, varscan2
- KIAA1614 | c.340A>G p.K114E | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV100851353; called by muse, mutect2, varscan2
- KIRREL3 | c.763T>A p.S255T | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV101585880; called by muse, mutect2, varscan2
- KMT2D | c.4251G>T p.M1417I | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.626); catalogued as COSV99979068, COSV99985593; called by muse, mutect2, varscan2
- KRT71 | c.181A>T p.S61C | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV99922399; called by muse, mutect2, varscan2
- KYNU | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV99933991; called by muse, mutect2, varscan2
- L1CAM | c.3521G>T p.G1174V | Missense Mutation (SNP) | VAF 102/118 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100649459; called by muse, mutect2, varscan2
- LACTB | c.616-2A>T p.X206_splice | Splice Site (SNP) | VAF 79/196 reads (40%) | catalogued as COSV99979059; called by muse, mutect2, varscan2
- LAMC2 | c.3124A>T p.M1042L | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99917941; called by muse, mutect2, varscan2
- LAMP3 | c.671A>T p.K224M | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99660766; called by muse, mutect2, varscan2
- LEP | c.361T>A p.W121R | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100451470; called by muse, mutect2, varscan2
- LHFPL4 | c.543C>G p.I181M | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.728); catalogued as COSV99805690; called by muse, mutect2
- LMBR1L | c.619C>A p.L207M | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99918994; called by muse, mutect2, varscan2
- LMF2 | c.1262A>T p.Y421F | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as COSV99327786; called by muse, mutect2, varscan2
- LONP2 | c.1932A>C p.E644D | Missense Mutation (SNP) | VAF 46/61 reads (75%) | SIFT tolerated (0.88); PolyPhen benign (0.013); catalogued as COSV99589502; called by muse, mutect2, varscan2
- LRP2 | c.7389A>T p.S2463= | Splice Region (SNP) | VAF 33/67 reads (49%) | catalogued as COSV99790194; called by muse, mutect2, varscan2
- LRRC7 | c.2416T>C p.W806R (on ENST00000651989 / NM_001370785.2; = p.W773R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99229618; called by muse, mutect2, varscan2
- MAD1L1 | c.1487A>T p.E496V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99767476; called by muse, mutect2, varscan2
- MET | c.3713A>T p.H1238L | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1562935856, COSV100577361, COSV59268957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MFSD11 | c.235A>C p.M79L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as rs773251685, COSV100334264; called by muse, mutect2, varscan2
- MINAR1 | c.804G>A p.M268I | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100549239; called by muse, mutect2, varscan2
- MINAR1 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.022); catalogued as COSV100549240; called by muse, mutect2, varscan2
- MMP12 | c.724T>A p.Y242N | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.534); catalogued as COSV100405071; called by muse, mutect2, varscan2
- MTA1 | c.1559C>T p.S520F | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs1187970091, COSV100495470; called by muse, mutect2, varscan2
- MTOR | c.1502T>A p.I501N | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100816646; called by muse, mutect2, varscan2
- MXRA5 | c.2256A>T p.K752N | Missense Mutation (SNP) | VAF 48/59 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as COSV99479126; called by muse, mutect2, varscan2
- MYBPHL | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.402); catalogued as COSV100848912; called by muse, mutect2, varscan2
- MYD88 | c.322A>T p.S108C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.855); catalogued as COSV57176102; called by muse, mutect2, varscan2
- MYLK | c.3302A>T p.K1101M | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV100659591; called by muse, mutect2, varscan2
- NARS2 | c.1376T>C p.V459A | Missense Mutation (SNP) | VAF 124/300 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs780902837, COSV99807535; called by muse, mutect2, varscan2
- NCAPD2 | c.203A>T p.H68L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.081); catalogued as COSV100217436; called by muse, mutect2, varscan2
- NDUFA8 | c.476A>T p.Q159L | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV101056877; called by muse, mutect2, varscan2
- NES | c.3770G>T p.G1257V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV100957985; called by muse, mutect2, varscan2
- NSRP1 | c.526A>T p.K176* | Nonsense Mutation (SNP) | VAF 31/79 reads (39%) | catalogued as COSV99898590; called by muse, mutect2, varscan2
- NUDT15 | c.67T>G p.C23G | Missense Mutation (SNP) | VAF 87/99 reads (88%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99320354; called by muse, mutect2, varscan2
- OBSCN | c.11549A>T p.Q3850L | Missense Mutation (SNP) | VAF 88/290 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); catalogued as COSV99484041; called by muse, mutect2, varscan2
- OR10H1 | c.107T>A p.L36Q | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100612496; called by muse, mutect2, varscan2
- OR13G1 | c.920A>T p.H307L | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV100687551; called by muse, mutect2, varscan2
- OR1J1 | c.203T>A p.L68H | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV99403259; called by muse, mutect2
- OR1J4 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.216); catalogued as COSV100534333; called by muse, mutect2, varscan2
- OR2T11 | c.481A>T p.M161L | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.817); catalogued as COSV100424954; called by muse, mutect2, varscan2
- PACS2 | c.1586G>T p.S529I | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100330982; called by muse, mutect2, varscan2
- PAK5 | c.841A>T p.T281S | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV100781669; called by muse, mutect2, varscan2
- PARD3B | c.395-2A>T p.X132_splice | Splice Site (SNP) | VAF 23/47 reads (49%) | catalogued as COSV100595116; called by muse, mutect2, varscan2
- PBX1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV63341268; called by muse, mutect2, varscan2
- PCDHGB1 | c.206A>T p.E69V | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV99546446; called by muse, mutect2, varscan2
- PGLYRP3 | c.377-2A>C p.X126_splice | Splice Site (SNP) | VAF 33/87 reads (38%) | catalogued as COSV99319927; called by muse, mutect2, varscan2
- PHACTR1 | c.352A>T p.R118W | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100278758; called by muse, mutect2, varscan2
- PLA2R1 | c.1098T>A p.V366= | Splice Region (SNP) | VAF 130/292 reads (45%) | catalogued as COSV99323546; called by muse, mutect2, varscan2
- PLEKHA6 | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV99692729; called by muse, mutect2, varscan2
- PPM1H | c.226T>A p.W76R | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99956501; called by muse, mutect2, varscan2
- PPP1R11 | c.30G>T p.E10D | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV54994664, COSV99748686; called by muse, mutect2, varscan2
- PRSS12 | c.808A>T p.S270C | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99628855; called by muse, mutect2, varscan2
- PUS1 | c.1254A>T p.E418D | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100435287; called by muse, mutect2, varscan2
- RAB3C | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 134/331 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV51431583, COSV51436350; called by muse, mutect2, varscan2
- RASSF4 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100437251; called by muse, mutect2, varscan2
- RESF1 | c.2284G>A p.V762I | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.321); catalogued as COSV57020793, COSV57022092; called by muse, mutect2
- RFTN1 | c.338A>T p.Q113L | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV100489853; called by muse, mutect2, varscan2
- RHPN2 | c.2009A>C p.K670T | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV99578269; called by muse, mutect2, varscan2
- RIMS3 | c.635A>T p.K212M | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV101013587; called by muse, mutect2, varscan2
- RPP40 | c.825A>T p.K275N | Missense Mutation (SNP) | VAF 50/203 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.259); catalogued as COSV100124147; called by muse, mutect2, varscan2
- RSPH10B | c.415A>T p.N139Y | Missense Mutation (SNP) | VAF 101/174 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100521432; called by muse, mutect2, varscan2
- RWDD3 | c.688A>T p.R230W | Missense Mutation (SNP) | VAF 92/221 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99811599, COSV99811723; called by muse, mutect2, varscan2
- RYR1 | c.4703A>T p.Q1568L | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV100616927; called by muse, mutect2, varscan2
- SAMD9 | c.1339A>G p.N447D | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV101180373; called by muse, mutect2, varscan2
- SDF2 | c.206A>T p.Y69F | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99898020; called by muse, mutect2, varscan2
- SFTA2 | c.200A>G p.H67R | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100764490; called by muse, mutect2, varscan2
- SIGLEC11 | c.558T>A p.C186* | Nonsense Mutation (SNP) | VAF 47/192 reads (24%) | catalogued as COSV101389648; called by muse, mutect2, varscan2
- SLC34A2 | c.114A>T p.T38= | Splice Region (SNP) | VAF 50/101 reads (50%) | catalogued as CD064631, COSV101158456; called by muse, mutect2, varscan2
- SLC35F2 | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as rs1015861030, COSV99758861; called by muse, mutect2, varscan2
- SLC38A11 | c.425G>A p.R142K (on ENST00000409149 / NM_001351539.1; = p.R120K on NM_173512.2) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as COSV100367036; called by muse, mutect2, varscan2
- SLC7A4 | c.1406T>A p.L469* | Nonsense Mutation (SNP) | VAF 29/79 reads (37%) | catalogued as COSV100298865; called by muse, mutect2, varscan2
- SLK | c.1765A>T p.M589L | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100212107; called by muse, mutect2, varscan2
- SLX4 | c.4700C>G p.S1567C | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99568515; called by muse, mutect2, varscan2
- SMCHD1 | c.4510A>T p.N1504Y | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as COSV99862534; called by muse, mutect2, varscan2
- SPAG17 | c.4079A>C p.H1360P | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100310499; called by muse, mutect2, varscan2
- SPEG | c.5332A>T p.T1778S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as COSV100405593; called by muse, mutect2, varscan2
- SULT6B1 | c.179T>A p.L60Q (on ENST00000535679 / NM_001367551.1; = p.L22Q on NM_001032377.2) | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99573320; called by muse, mutect2, varscan2
- TTC27 | c.1832A>T p.K611I | Missense Mutation (SNP) | VAF 113/276 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100513560; called by muse, mutect2, varscan2
- TTN | c.77903T>A p.V25968D (on ENST00000591111; = p.V18544D on NM_003319.4) | Missense Mutation (SNP) | VAF 34/104 reads (33%) | PolyPhen benign (0.054); catalogued as COSV100628999; called by muse, mutect2, varscan2
- TTN | c.69791C>T p.P23264L (on ENST00000591111; = p.P15840L on NM_003319.4) | Missense Mutation (SNP) | VAF 31/94 reads (33%) | PolyPhen possibly damaging (0.747); catalogued as COSV100629001; called by muse, mutect2, varscan2
- TTN | c.11329T>A p.Y3777N (on ENST00000591111; = p.Y3731N on NM_003319.4) | Missense Mutation (SNP) | VAF 28/75 reads (37%) | catalogued as COSV100629004; called by muse, mutect2, varscan2
- VPS13C | c.7402A>T p.S2468C (on ENST00000644861 / NM_020821.3; = p.S2425C on NM_017684.5) | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as COSV99830127; called by muse, mutect2, varscan2
- VPS54 | c.1202A>T p.Y401F | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.122); catalogued as COSV99708705; called by muse, mutect2
- VWF | c.7099T>G p.C2367G | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99780096; called by muse, mutect2, varscan2
- WDFY3 | c.5239A>T p.N1747Y | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV99885567; called by muse, mutect2, varscan2
- YIPF2 | c.909C>G p.I303M | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV99450312; called by muse, mutect2, varscan2
- ZBTB48 | c.499A>T p.R167* | Nonsense Mutation (SNP) | VAF 31/72 reads (43%) | catalogued as COSV100039857; called by muse, mutect2, varscan2
- ZNF248 | c.408del p.Y137Ifs*9 | Frame Shift Del (DEL) | VAF 56/162 reads (35%) | catalogued as COSV61998250; called by mutect2, pindel, varscan2
- ZNF43 | c.1057C>A p.Q353K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV100731961; called by muse, mutect2, varscan2
- ZNF648 | c.1405A>T p.I469F | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV100374790; called by muse, mutect2, varscan2
- ADORA2A | c.650_663delinsT p.P217Lfs*63 | Frame Shift Del (DEL) | VAF 21/43 reads (49%) | called by pindel, varscan2*
- CDKL5 | c.2047-22_2071del p.X683_splice | Splice Site (DEL) | VAF 48/53 reads (91%) | called by mutect2, pindel
- CELSR2 | c.6828del p.I2277Sfs*7 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
- COL20A1 | c.2650_2659del p.T884Sfs*35 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- IGHG1 | c.89A>G p.K30R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KIAA0586 | c.4070_4076delinsAT p.L1357Yfs*4 (on ENST00000619416 / NM_001244190.2; = p.L1296Yfs*4 on NM_014749.5) | Frame Shift Del (DEL) | VAF 41/109 reads (38%) | called by pindel, varscan2*
- MASP2 | c.1317_1343del p.T440_G448del | In Frame Del (DEL) | VAF 31/105 reads (30%) | called by mutect2, pindel, varscan2
- NANOG | c.803A>T p.E268V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- SPAG17 | c.4889del p.N1630Ifs*31 | Frame Shift Del (DEL) | VAF 83/207 reads (40%) | called by mutect2, pindel, varscan2
- TP53 | c.683_686del p.D228Vfs*18 | Frame Shift Del (DEL) | VAF 21/30 reads (70%) | called by mutect2, pindel, varscan2
- ACAD8 | c.300G>T p.L100= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV99844557; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1713A>T p.A571= | Silent (SNP) | VAF 12/24 reads (50%) | called by mutect2, varscan2
- B3GAT1 | c.273C>A p.P91= | Silent (SNP) | VAF 54/113 reads (48%) | catalogued as COSV57000730; called by muse, mutect2, varscan2
- CDH8 | c.1674G>A p.L558= | Silent (SNP) | VAF 54/74 reads (73%) | catalogued as COSV100184044; called by muse, varscan2
- CDYL | c.1194C>G p.V398= (on ENST00000328908 / NM_001368125.1; = p.V344= on NM_004824.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 123/203 reads (61%) | catalogued as COSV100190109; called by muse, mutect2, varscan2
- CHRNB3 | c.660T>C p.Y220= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as COSV99251482; called by muse, mutect2, varscan2
- COL20A1 | c.1851T>A p.S617= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100491417; called by muse, mutect2, varscan2
- DGKZ | c.1536A>T p.R512= (on ENST00000454345 / NM_001105540.2; = p.R324= on NM_003646.4) | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV100551947; called by muse, mutect2, varscan2
- DHX30 | c.2163A>G p.P721= (on ENST00000445061 / NM_138615.3; = p.P682= on NM_014966.3) | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as rs1002179549, COSV99276228; called by muse, mutect2, varscan2
- DNAAF1 | c.1095T>A p.P365= | Silent (SNP) | VAF 42/56 reads (75%) | catalogued as COSV100533823; called by muse, mutect2, varscan2
- DPP10 | c.343T>C p.L115= | Silent (SNP) | VAF 108/252 reads (43%) | catalogued as rs139947044; called by muse, mutect2, varscan2
- DPY19L1 | c.45T>A p.P15= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100204997; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1566T>A p.A522= (on ENST00000361735 / NM_015935.5; = p.A436= on NM_014955.3) | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as COSV100676039; called by muse, mutect2, varscan2
- EIF2B3 | c.1131A>T p.S377= | Silent (SNP) | VAF 44/87 reads (51%) | catalogued as COSV100838986; called by muse, mutect2, varscan2
- EYA1 | c.1266T>A p.T422= | Silent (SNP) | VAF 59/198 reads (30%) | catalogued as COSV100380242; called by muse, mutect2, varscan2
- HRH1 | c.210G>A p.S70= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as rs770524896, COSV101229111; called by muse, mutect2, varscan2
- IL17RD | c.987A>T p.I329= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV99578072; called by muse, mutect2, varscan2
- JAG2 | c.3096T>A p.P1032= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV100078811; called by muse, mutect2, varscan2
- KASH5 | c.570T>A p.A190= | Silent (SNP) | VAF 49/114 reads (43%) | catalogued as COSV101483499; called by muse, mutect2, varscan2
- KIF26B | c.4725T>A p.A1575= | Silent (SNP) | VAF 57/208 reads (27%) | catalogued as COSV100833375; called by muse, mutect2, varscan2
- LCA5 | c.2082A>T p.V694= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV100878365; called by muse, mutect2, varscan2
- MPDZ | c.4032A>G p.L1344= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as COSV100057496; called by muse, varscan2
- MUC6 | c.7122C>A p.G2374= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs372205312, COSV100173326; called by muse, mutect2, varscan2
- NUP153 | c.4299G>T p.S1433= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV104382336, COSV99467842, COSV99467943; called by muse, mutect2, varscan2
- NXN | c.783C>G p.A261= | Silent (SNP) | VAF 39/49 reads (80%) | catalogued as COSV100403486; called by muse, mutect2, varscan2
- PARP8 | c.2337C>T p.F779= | Silent (SNP) | VAF 122/266 reads (46%) | catalogued as COSV99892737; called by muse, varscan2
- PDGFRA | c.285A>T p.T95= | Silent (SNP) | VAF 50/113 reads (44%) | catalogued as COSV99957575; called by muse, mutect2, varscan2
- RAPGEF3 | c.882G>C p.V294= (on ENST00000389212; = p.V252= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99406826; called by muse, mutect2, varscan2
- RPN1 | c.354A>T p.P118= | Silent (SNP) | VAF 43/82 reads (52%) | catalogued as COSV99957270; called by muse, mutect2, varscan2
- SLC22A10 | c.111A>G p.L37= | Silent (SNP) | VAF 60/116 reads (52%) | catalogued as rs537943997, COSV100236024; called by muse, mutect2, varscan2
- SLC25A48 | c.207T>A p.I69= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV99192196; called by muse, mutect2, varscan2
- SLC4A3 | c.2289T>A p.L763= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99813196; called by muse, mutect2, varscan2
- STAG3 | c.2022G>C p.L674= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as COSV100426184; called by muse, mutect2, varscan2
- SYDE1 | c.1002T>A p.L334= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99655125; called by muse, mutect2, varscan2
- SYT6 | c.1086G>A p.L362= (on ENST00000610222 / NM_001366225.1; = p.L277= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as rs1387249346, COSV101059747; called by muse, mutect2, varscan2
- TAAR1 | c.489A>T p.L163= | Silent (SNP) | VAF 46/104 reads (44%) | catalogued as COSV99257748; called by muse, mutect2, varscan2
- TAOK2 | c.432C>T p.S144= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as COSV99665389; called by muse, mutect2, varscan2
- TCEA2 | c.738C>T p.H246= | Silent (SNP) | VAF 67/219 reads (31%) | catalogued as COSV100180898; called by muse, mutect2, varscan2
- TMIGD2 | c.492T>A p.A164= | Silent (SNP) | VAF 28/36 reads (78%) | catalogued as COSV100010502; called by muse, varscan2
- TP53BP1 | c.3372G>C p.V1124= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as rs952443675, COSV99781451; called by muse, mutect2
- TTC21B | c.1485C>G p.V495= | Silent (SNP) | VAF 14/318 reads (4%) | catalogued as COSV99692834; called by muse, mutect2
- UBE4A | c.1440A>T p.V480= (on ENST00000252108 / NM_001204077.2; = p.V487= on NM_004788.4) | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV99348579; called by muse, mutect2, varscan2
- UTP20 | c.4896A>T p.I1632= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV99882505; called by muse, mutect2, varscan2
- XKR4 | c.1650C>A p.S550= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as COSV100533943, COSV59316514; called by muse, mutect2, varscan2
- ZDHHC18 | c.714C>T p.Y238= | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as rs759970162, COSV65145531; called by muse, mutect2, varscan2
- ZMYM4 | c.4383T>C p.N1461= | Silent (SNP) | VAF 56/110 reads (51%) | catalogued as COSV100111108; called by muse, mutect2, varscan2
- ZNF396 | c.429A>G p.G143= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV100108651; called by muse, mutect2
- C8orf31 | n.615A>T | RNA (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- MIR15A | n.18A>T | RNA (SNP) | VAF 89/105 reads (85%) | called by muse, mutect2, varscan2
- SSPOP | n.5527G>T | RNA (SNP) | VAF 27/51 reads (53%) | catalogued as COSV100022983, COSV50489055; called by muse, mutect2, varscan2
- ZNF767P | n.594A>T | RNA (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2
